Gene-level copy-number profile of specimen HCM-BROD-0962-C16-85A from HCMI case HCM-BROD-0962-C16, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; Tumor grade: G3; Age at diagnosis: 62.3 years (22,747 days).
Specimen HCM-BROD-0962-C16-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 10.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2a8b376d-21bb-4619-b8d1-797881de3404.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0962-C16-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/acc6e718-534f-4f24-a060-f798df5e607f

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 457; copy number 1: 10; copy number 2: 7,398; copy number 3: 18,321; copy number 4: 26,215; copy number 5: 5,290; copy number 6: 288; copy number 7: 269; copy number 8: 155; copy number 9: 131; copy number 10: 33; copy number 11: 8; copy number 12: 73; copy number 13: 2; copy number 14: 33; copy number 16: 7; copy number 18: 9; copy number 19: 11; copy number 20: 12; copy number 21: 9; copy number 22: 10; copy number 24: 8; copy number 25: 29; copy number 26: 15; copy number 28: 1; copy number 30: 8; copy number 31: 9; copy number 36: 10; copy number 41: 15; copy number 44: 18; copy number 46: 9; copy number 47: 4; copy number 49: 4; copy number 50: 1; copy number 51: 1; copy number 53: 3; copy number 54: 11; copy number 56: 1; copy number 60: 21.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 506 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:50,756,892–52,309,163, 64 genes, copy number 9–10 (within-gene range 8–10) (broad region; genes not listed).
- chr12:52,514,575–52,834,311, 23 genes, copy number 9: KRT5, KRT71, KRT74, KRT72, KRT73-AS1, KRT73, KRT128P, KRT2, KRT1, KRT77, AC055716.3, KRT126P, KRT125P, AC055716.2, AC055716.1, BTBD10P1, KRT127P, ARL2BPP2, KRT76, AC107016.2, KRT3, KRT4, KRT79.
- chr12:52,948,871–53,142,327, 12 genes, copy number 9 (within-gene range 7–9): KRT18, EIF4B, AC068888.2, AC068888.1, TNS2, MIR6757, SPRYD3, IGFBP6, SOAT2, VTI1BP3, RNU6-333P, HIGD1AP1.
- chr12:54,121,277–54,189,008, 1 gene, copy number 9 (within-gene range 6–9): SMUG1.
- chr12:54,145,069–54,168,595, 3 genes, copy number 9: AC023794.5, AC023794.4, AC023794.1.
- chr12:54,830,518–55,872,602, 55 genes, copy number 9–10: MUCL1, TESPA1, AC027287.2, NEUROD4, OR9K1P, AC027287.1, OR9K2, OR9R1P, OR10U1P, OR10A7, OR6C74, OR6C69P, OR6C72P, OR6C6, OR6C5P, OR6C1, OR6C3, OR6C7P, OR6C75, OR6C71P, OR6C66P, OR6C65, PHC1P1, OR6C76, AC122685.1, OR6C2, OR6C70, OR6C68, OR6C64P, OR6C4, OR2AP1, OR6U2P, OR10P1, AC009779.4, OR10AE3P, PSMB3P1, AC009779.5, METTL7B, ITGA7, AC009779.3, BLOC1S1, RDH5, CD63, AC009779.2, Metazoa_SRP, AC009779.1, GDF11, SARNP, AC023055.1, AC073487.1, ORMDL2, DNAJC14, TMEM198B, MMP19, OLA1P3.
- chr12:58,872,149–59,586,943, 10 genes, copy number 11–19: LRIG3, AC068305.2, RPS6P22, AC068305.1, AC108721.2, AC108721.1, RNU6-279P, RNU6-871P, LINC02448, RNU4-20P.
- chr12:64,507,001–64,697,564, 1 gene, copy number 13 (within-gene range 5–16): RASSF3.
- chr12:64,654,060–64,655,019, 1 gene, copy number 13 (within-gene range 13–16): AC078962.3.
- chr12:64,713,445–64,759,431, 1 gene, copy number 9: GNS.
- chr12:65,824,460–68,253,604, 45 genes, copy number 14–22 (within-gene range 7–22): HMGA2, AC107308.1, HMGA2-AS1, AC090673.1, MIR6074, LINC02425, RPL21P18, RNA5SP362, LLPH, AC078927.1, LLPH-DT, TMBIM4, IRAK3, RBMS1P1, MIR6502, AC078889.1, PDCL3P7, RN7SKP166, HELB, GRIP1, OSBPL9P5, OSBPL9P4, AC073530.1, AC073530.2, RAB11AP2, GGTA2P, CAND1, MRPL40P1, NTAN1P3, LINC02420, LINC02408, LINC02442, DYRK2, AC078777.1, LINC02421, AC022513.1, LINC01479, AC005294.1, IFNG-AS1, RPL39P28, HNRNPA1P70, AC007458.1, IFNG, IL26, IL22.
- chr12:68,575,858–68,671,901, 5 genes, copy number 9: Metazoa_SRP, RAP1B, RPL10P12, SNORA70G, ATP5PDP4.
- chr12:68,746,125–71,800,286, 61 genes, copy number 11–56 (broad region; genes not listed).
- chr20:41,402,083–41,685,091, 5 genes, copy number 14: CHD6, AL031667.2, AL031667.3, RPL12P11, RNU6-1018P.
- chr20:47,209,214–47,656,877, 10 genes, copy number 41–47 (within-gene range 2–47): ZMYND8, AL031666.2, AL031666.3, AL031666.1, LINC01754, RPL35AP, RNU6-497P, RNU6-563P, NCOA3, AL034418.1.
- chr20:49,982,980–50,321,342, 13 genes, copy number 12: SNAI1, TRERNA1, UBE2V1, PEDS1-UBE2V1, PEDS1, LINC01275, AL161937.1, LINC01273, CEBPB-AS1, CEBPB, PELATON, LINC01270, LINC01271.
- chr20:51,782,331–53,668,758, 29 genes, copy number 30–44: SALL4, LINC01429, RNU6-347P, RNU7-6P, ZFP64, AL109984.1, ERP29P1, LINC01524, AL109610.1, AL049765.2, AL049765.1, MRPS33P4, AL031674.1, AL121902.1, RPL36P1, TSHZ2, RN7SKP184, AL391097.3, AL391097.1, AL391097.2, AL109930.1, AL354993.1, PPIAP10, AL354993.2, Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P.
- chr20:56,205,052–56,299,160, 4 genes, copy number 49: RNA5SP487, MC3R, AL139824.2, AL139824.1.
- chr20:57,599,695–60,083,872, 57 genes, copy number 14–46: AL035541.1, ZBP1, PMEPA1, NKILA, AL162291.1, AL354984.1, LINC01742, AL354984.2, AL354984.3, C20orf85, ANKRD60, PPP4R1L, RAB22A, VAPB, APCDD1L, APCDD1L-DT, AL050327.1, LINC01711, STX16, STX16-NPEPL1, NPEPL1, AL139349.1, PIEZO1P2, AL132655.3, AL132655.2, MIR296, MIR298, GNAS-AS1, AL132655.1, GNAS, AL132655.7, AL132655.6, AL132655.4, AL132655.5, AL121917.1, AL121917.2, NELFCD, CTSZ, TUBB1, ATP5F1E, PRELID3B, MRPS16P2, ZNF831, EDN3, AL035250.1, AL035250.2, PIEZO1P1, AL389889.1, PHACTR3, PHACTR3-AS1, RNU7-141P, SYCP2, FAM217B, PPP1R3D, CDH26, C20orf197, AL132822.1.
- chr20:60,564,562–62,814,000, 56 genes, copy number 12–60: MIR548AG2, AL117372.1, AL139348.1, AL121910.1, LINC01718, CDH4, AL365229.1, BX640515.1, AL160412.1, AL162457.1, AL162457.2, TAF4, MIR1257, AL137077.1, MIR3195, LSM14B, PSMA7, SS18L1, MTG2, HRH3, OSBPL2, ADRM1, AL354836.1, LAMA5, MIR4758, LAMA5-AS1, AL121832.2, RPS21, CABLES2, AL121832.3, RBBP8NL, AL121832.1, GATA5, AL499627.2, AL499627.1, MIR1-1HG-AS1, MIR1-1HG, MIR1-1, MIR133A2, RPL7P3, BX640514.1, BX640514.2, AL450469.2, AL450469.1, AL357033.1, SLCO4A1, AL357033.4, AL357033.3, SLCO4A1-AS1, LINC00686, NTSR1, AL357033.2, LINC00659, MRGBP, OGFR-AS1, OGFR.
- chr22:20,299,760–21,070,097, 50 genes, copy number 12: AC007663.1, DGCR6L, AC007663.4, AC007663.3, FAM230G, AC007731.2, AC007731.5, USP41, ZNF74, RNU6-225P, SCARF2, AC007731.4, KLHL22, AC007731.1, RNY1P9, Y_RNA, RN7SL812P, KRT18P5, MED15, AC007731.3, CCDC74BP1, SMPD4P1, IGLL4P, SLC9A3P2, ABHD17AP4, POM121L4P, BCRP5, TMEM191A, PI4KA, SERPIND1, SNAP29, AC007308.1, CRKL, LINC01637, AIFM3, AC002470.2, AC002470.1, LZTR1, THAP7, THAP7-AS1, AC002472.2, TUBA3FP, P2RX6, AC002472.3, SLC7A4, AC002472.1, MIR649, P2RX6P, LRRC74B, TUBA3GP.

Autosomal genes at a single copy (total copy number 1): 10. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
